Somatic mutation profile of tumor specimen TCGA-28-1745-01B (aliquot TCGA-28-1745-01B-01W-0643-08) from TCGA case TCGA-28-1745, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.2 years (27,817 days).
Specimen TCGA-28-1745-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2fcdae2-8776-4580-83a4-ea2c92ccae96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1745-10A (Blood Derived Normal), aliquot TCGA-28-1745-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a836c839-cd3f-442a-9bdb-33e4e59b4ade

The open-access MAF lists 50 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 33, Silent 9, Nonsense Mutation 5, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 50/241 reads (21%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAT2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as rs773519162, COSV52793296; called by muse, varscan2
- ADGRL2 | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99587767; called by muse, mutect2, varscan2
- BUB1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.945); catalogued as COSV100241039; called by muse, mutect2, varscan2
- CASR | c.2393G>C p.S798T (on ENST00000490131; = p.S875T on NM_000388.4) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99948638; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1552C>A p.L518I | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV100575244; called by muse, mutect2
- COL2A1 | c.4073A>G p.H1358R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs749485192, COSV100475903; called by muse, mutect2, varscan2
- EGFR | c.3032T>A p.V1011E | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV99288542; called by muse, mutect2, varscan2
- EPHA5 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV56673745, COSV99897433; called by muse, mutect2
- FAM47A | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.697); catalogued as rs375344520, COSV60498157; called by muse, varscan2
- GABRA3 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750973085, COSV64795435; called by muse, mutect2, varscan2
- IVL | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.622); catalogued as rs979169470, COSV100908133; called by muse, mutect2
- KCNT2 | c.460-2A>T p.X154_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99652445; called by muse, mutect2, varscan2
- KDM1B | c.2399G>A p.R800K (on ENST00000449850; = p.R567K on NM_153042.4) | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as COSV99788772; called by muse, mutect2
- KRI1 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100469879; called by muse, mutect2
- LEMD2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99540662; called by muse, mutect2
- MAPK7 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759623746, COSV100218821, COSV100218879; called by muse, mutect2, varscan2
- MYOM2 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 74/1102 reads (7%) | catalogued as COSV100037046; called by muse, mutect2
- NCKAP1L | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867197350, COSV53203951; called by muse, mutect2
- NQO2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100583164; called by muse, mutect2
- OR2T12 | c.933C>G p.H311Q | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100527639; called by muse, mutect2
- OR6C3 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as COSV101110324; called by muse, mutect2, varscan2
- PCSK2 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs142020979; called by muse, mutect2, varscan2
- PRR14 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1567539373, COSV99788325; called by mutect2, varscan2
- PTPN3 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1286166339; called by muse, mutect2
- RAPGEF6 | c.3018G>T p.Q1006H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as COSV99725777; called by muse, mutect2
- SLFN11 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 35/212 reads (17%) | catalogued as COSV100390426, COSV57698353; called by muse, mutect2, varscan2
- SOX30 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs571563119, COSV53936569; called by muse, mutect2
- SPAG9 | c.2611C>T p.P871S (on ENST00000262013 / NM_001130528.3; = p.P857S on NM_003971.6) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100004772; called by muse, mutect2
- SPRY4 | c.75del p.M26Cfs*18 (on ENST00000434127 / NM_001127496.3; = p.M49Cfs*18 on NM_030964.4) | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs760818480; called by mutect2, pindel, varscan2
- TCP11L2 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV100135251; called by muse, mutect2
- TEC | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 24/1019 reads (2%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV101202568; called by muse, mutect2
- THEMIS | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100965295; called by muse, mutect2
- TLE1 | c.948A>T p.K316N | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100916271; called by muse, mutect2, varscan2
- TMEM144 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV99646690; called by muse, mutect2, varscan2
- WDR47 | c.1252G>A p.E418K (on ENST00000369962 / NM_001142551.2; = p.E419K on NM_014969.5) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100728273; called by muse, mutect2, varscan2
- XPNPEP3 | c.1306A>C p.M436L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100846650; called by muse, mutect2, varscan2
- ZFAT | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100914390; called by muse, mutect2, varscan2
- GPR26 | c.850T>A p.Y284N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRGUK | c.176_178del p.S59del | In Frame Del (DEL) | VAF 6/49 reads (12%) | called by pindel, varscan2
- NOD2 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- DNAH2 | c.5643C>T p.A1881= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs144218986; called by muse, mutect2, varscan2
- GK2 | c.1401G>A p.E467= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100725888; called by muse, mutect2
- GLB1 | c.1710T>C p.F570= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100257094; called by muse, mutect2
- ITGAE | c.1014C>T p.A338= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99560626; called by mutect2, varscan2
- KBTBD4 | c.1455G>A p.K485= | Silent (SNP) | VAF 13/233 reads (6%) | catalogued as COSV100442841; called by muse, mutect2
- NT5DC3 | c.1500C>T p.Y500= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV101230908; called by muse, mutect2, varscan2
- PSG4 | c.441C>T p.P147= | Silent (SNP) | VAF 29/256 reads (11%) | catalogued as rs778299521, COSV99736650; called by muse, mutect2, varscan2
- TDRD7 | c.1413A>G p.E471= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100795506; called by muse, mutect2
- TNC | c.639C>T p.G213= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs770598416, COSV60781519; called by muse, mutect2, varscan2
